Somatic mutation profile of tumor specimen MMRF_1995_1_BM_CD138pos (aliquot MMRF_1995_1_BM_CD138pos_T1_KHS5U_L08118) from MMRF case MMRF_1995, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,526 days).
Specimen MMRF_1995_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81666609-10a5-4583-9468-be2205f44455.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1995_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1995_1_PB_WBC_C2_KHS5U_L08119; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1697df67-7e8c-425a-baca-adef8977b43e

The open-access MAF lists 182 somatic variants for this specimen: 64 protein-altering or splice-affecting, 25 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 47, Silent 25, Intron 19, 5'UTR 9, 3'Flank 8, 5'Flank 6, Nonsense Mutation 6, RNA 4, Frame Shift Del 4, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.10311G>T p.W3437C | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV101316426; called by muse, mutect2
- AGO4 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs545951478, COSV64616360; called by muse, mutect2, varscan2
- ANXA10 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as rs1248658830; called by muse, mutect2
- BARX1 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1201657492; called by muse, mutect2, varscan2
- CACHD1 | c.1523T>C p.F508S | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV51558022; called by muse, mutect2, varscan2
- CACNB2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1422197851; called by muse, mutect2, varscan2
- CCDC74B | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs147577700, COSV100134805; called by muse, mutect2, varscan2
- CD177 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 100/500 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541810499, COSV100946081; called by muse, mutect2, varscan2
- CHST13 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1231021325, COSV60043121; called by muse, mutect2, varscan2
- CPSF1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs782090510, COSV62938935; called by muse, mutect2, varscan2
- DNAH3 | c.3370A>C p.M1124L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV99770788; called by muse, mutect2, varscan2
- DUSP2 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1307944043; called by muse, mutect2, varscan2
- IGHV2-70 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 46/120 reads (38%) | catalogued as rs61733526; called by muse, varscan2
- IGLV3-1 | c.133A>C p.K45Q | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs187892119; called by muse, varscan2
- KCNG1 | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as COSV65368374; called by muse, mutect2, varscan2
- MAGEA10 | c.157C>G p.P53A | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV54882680; called by muse, mutect2, varscan2
- METTL27 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99936434; called by muse, mutect2, varscan2
- MYO15A | c.5900G>A p.R1967H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs780235460; called by muse, mutect2, varscan2
- NUP210L | c.3073A>C p.K1025Q | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs751685912; called by muse, mutect2, varscan2
- OTOG | c.8057C>T p.P2686L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs761369572; called by muse, mutect2, varscan2
- PAPSS1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99491964; called by muse, mutect2, varscan2
- PCDHB15 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs1554291881, COSV50912977; called by muse, mutect2, varscan2
- PIGR | c.754T>G p.S252A | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs1375768707; called by muse, mutect2, varscan2
- PIGZ | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 12/192 reads (6%) | catalogued as rs779107630, COSV53013643; called by muse, mutect2
- PPFIA3 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs759215269, COSV53256908; called by muse, mutect2, varscan2
- SCRIB | c.2138A>G p.N713S | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as rs782321933; called by muse, mutect2, varscan2
- SLC15A3 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763376655, COSV99135634; called by muse, mutect2, varscan2
- SORBS3 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs775027920; called by muse, mutect2, varscan2
- TEAD1 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV57566417; called by muse, mutect2
- UACA | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748426431; called by muse, mutect2, varscan2
- ACTG1 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD30A | c.3396del p.F1133Lfs*7 (on ENST00000611781; = p.F1077Lfs*7 on NM_052997.2) | Frame Shift Del (DEL) | VAF 57/193 reads (30%) | called by mutect2, pindel, varscan2
- ANKRD46 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- ANXA13 | c.428A>C p.D143A | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- APLF | c.1366G>C p.V456L | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ASXL1 | c.2087T>C p.L696P | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATCAY | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 73/364 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- BAAT | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CAPZB | c.456C>G p.H152Q | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHD5 | c.5017G>A p.E1673K | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CXADR | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG1 | c.2624A>T p.D875V (on ENST00000419354 / NM_001290983.1; = p.D897V on NM_004087.2) | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FYCO1 | c.3313T>A p.Y1105N | Missense Mutation (SNP) | VAF 113/173 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- GNGT2 | c.77G>C p.R26T | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.1870+2T>A p.X624_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2
- IDO1 | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, varscan2
- ISL1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MATK | c.1180G>T p.E394* (on ENST00000310132 / NM_139355.3; = p.E395* on NM_002378.4) | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2
- MGAM | c.5384A>T p.K1795I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MIA3 | c.1776A>C p.R592S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MORC1 | c.2644_2645del p.K882Efs*9 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- MUC2 | c.1681C>T p.H561Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- NR3C1 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.005); called by muse, varscan2
- PRKACA | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RANBP3 | c.1039G>C p.E347Q (on ENST00000340578 / NM_007322.3; = p.E342Q on NM_003624.3) | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2
- RBM24 | c.530C>A p.P177H (on ENST00000379052 / NM_001143942.2; = p.P132H on NM_153020.2) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- RFPL4B | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SP140 | c.1312_1318del p.Y438Mfs*71 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1432C>G p.P478A (on ENST00000367255 / NM_182961.4; = p.P485A on NM_033071.3) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- TFE3 | c.569_583del p.H190_A194del | In Frame Del (DEL) | VAF 14/28 reads (50%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.5009T>G p.L1670* | Nonsense Mutation (SNP) | VAF 114/289 reads (39%) | called by muse, varscan2
- ZNF559 | c.1206_1207del p.H403Sfs*7 | Frame Shift Del (DEL) | VAF 37/228 reads (16%) | called by mutect2, pindel, varscan2
- ZNF768 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ACO1 | c.114G>A p.S38= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as rs754861122; called by muse, mutect2, varscan2
- ACTG1 | c.93T>C p.F31= | Silent (SNP) | VAF 72/232 reads (31%) | catalogued as rs1568063103; called by muse, varscan2
- ASB17 | c.844C>T p.L282= | Silent (SNP) | VAF 71/178 reads (40%) | catalogued as COSV52411198; called by muse, mutect2, varscan2
- B4GALT7 | c.772C>T p.L258= | Silent (SNP) | VAF 55/209 reads (26%) | catalogued as rs1174249047; called by muse, mutect2, varscan2
- BTK | c.1113C>T p.S371= | Silent (SNP) | VAF 25/38 reads (66%) | called by muse, mutect2, varscan2
- CCNL2 | c.213C>T p.T71= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs766026340; called by muse, mutect2
- DCLK3 | c.192C>T p.S64= | Silent (SNP) | VAF 55/226 reads (24%) | catalogued as rs373096178; called by muse, mutect2, varscan2
- DMRT3 | c.54G>A p.P18= | Silent (SNP) | VAF 3/57 reads (5%) | catalogued as rs1194325590, COSV99505843; called by muse, mutect2
- ESRP1 | c.456T>C p.D152= | Silent (SNP) | VAF 80/238 reads (34%) | called by muse, mutect2, varscan2
- HOOK2 | c.1755C>T p.N585= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- IGKC | c.318G>A p.E106= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs1028593629; called by muse, mutect2, varscan2
- KCNG3 | c.441G>A p.A147= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- KLHL31 | c.1056A>C p.P352= | Silent (SNP) | VAF 68/193 reads (35%) | called by muse, mutect2, varscan2
- MAP2K1 | c.360G>A p.E120= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- MSANTD1 | c.427C>T p.L143= | Silent (SNP) | VAF 51/145 reads (35%) | called by muse, mutect2, varscan2
- NABP1 | c.33A>T p.I11= | Silent (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- NKX2-5 | c.825C>T p.P275= | Silent (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- P3H4 | c.175C>T p.L59= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs782011053; called by muse, mutect2, varscan2
- PCDHA6 | c.1863G>A p.P621= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs782199993, COSV65343457; called by muse, mutect2, varscan2
- SAFB2 | c.1425A>G p.G475= | Silent (SNP) | VAF 51/143 reads (36%) | called by muse, mutect2, varscan2
- TMEM235 | c.357G>A p.L119= | Silent (SNP) | VAF 61/151 reads (40%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.2262C>T p.S754= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs775210061, COSV99271170; called by muse, mutect2, varscan2
- ZNF257 | c.756T>C p.T252= | Silent (SNP) | VAF 72/174 reads (41%) | called by muse, mutect2, varscan2
- ZNF335 | c.3501C>T p.S1167= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ZSCAN10 | c.351T>C p.P117= (on ENST00000252463; = p.P172= on NM_032805.3) | Silent (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- ADAR | c.*1587C>T | 3'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- ALDH1A3 | chr15:100877839 C>T | 5'Flank (SNP) | VAF 22/178 reads (12%) | catalogued as rs1233574527; called by muse, mutect2, varscan2
- AR | c.*1238G>T | 3'UTR (SNP) | VAF 48/71 reads (68%) | catalogued as rs1465756888; called by muse, mutect2, varscan2
- ARHGAP26 | c.*5382del | 3'UTR (DEL) | VAF 54/135 reads (40%) | called by mutect2, pindel, varscan2
- ARHGEF16 | c.589-63A>G | Intron (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914089 C>T | 5'Flank (SNP) | VAF 110/313 reads (35%) | catalogued as rs1212603450; called by muse, mutect2, varscan2
- ARRB1 | c.*976C>T | 3'UTR (SNP) | VAF 68/118 reads (58%) | catalogued as rs996970778; called by muse, mutect2, varscan2
- AUTS2 | c.*572A>G | 3'UTR (SNP) | VAF 18/40 reads (45%) | catalogued as rs1004602280; called by muse, mutect2, varscan2
- BLID | c.-262G>T | 5'UTR (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- C8orf34 | c.1549+4005G>A | Intron (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81948894 T>C | 3'Flank (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- CBX8 | c.*840T>C | 3'UTR (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- CD180 | c.-97T>G | 5'UTR (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- CHMP1B | c.*455T>A | 3'UTR (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- CLVS1 | c.*533C>A | 3'UTR (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- CNOT7 | c.*136A>C | 3'UTR (SNP) | VAF 39/130 reads (30%) | called by muse, mutect2, varscan2
- COL5A2 | c.*1560G>T | 3'UTR (SNP) | VAF 31/67 reads (46%) | catalogued as rs565023897; called by muse, mutect2, varscan2
- CRACR2A | c.1271+1254A>G | Intron (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*4753C>T | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- CROCCP2 | n.2321G>C | RNA (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- CSMD2 | c.6862+1722C>T | Intron (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- CTDP1 | c.*537C>T | 3'UTR (SNP) | VAF 28/77 reads (36%) | catalogued as rs1040556936; called by muse, mutect2, varscan2
- CYB5A | c.289-1094dup | Intron (INS) | VAF 31/145 reads (21%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.*4476dup | 3'UTR (INS) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.*4702G>A | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- DNAL4 | c.*143C>T | 3'UTR (SNP) | VAF 30/107 reads (28%) | catalogued as rs1361187741; called by muse, mutect2, varscan2
- DOCK6 | c.309-74T>G | Intron (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13893351 G>T | 3'Flank (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- ETV1 | c.*1449A>G | 3'UTR (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- FAM135B | c.3638+95T>G | Intron (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- FAM234A | chr16:234764 del C | 5'Flank (DEL) | VAF 21/62 reads (34%) | catalogued as rs1046068718; called by mutect2, pindel, varscan2
- FBLN1 | c.1697+7822G>A | Intron (SNP) | VAF 20/83 reads (24%) | catalogued as rs995592522; called by muse, mutect2, varscan2
- GEMIN5 | c.*518A>T | 3'UTR (SNP) | VAF 18/98 reads (18%) | catalogued as rs753466973; called by muse, mutect2, varscan2
- GLIPR1 | c.*2098T>C | 3'UTR (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- GLYR1 | c.*785G>C | 3'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- GNA12 | c.*1066A>C | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- GPATCH2 | c.*753T>A | 3'UTR (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- GSPT1 | chr16:11872978 G>A | 3'Flank (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- HLA-DMA | c.374-13A>G | Intron (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- HSPB11 | c.205+148A>G | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- HTR3D | c.228-29C>T | Intron (SNP) | VAF 65/274 reads (24%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899627 C>T | 3'Flank (SNP) | VAF 41/116 reads (35%) | catalogued as rs190433268; called by muse, mutect2, varscan2
- IL1RAP | c.*569T>G | 3'UTR (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- INPP4B | c.2643-607A>G | Intron (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- JTB | c.-404A>C | 5'UTR (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- KIF16B | c.*100T>C | 3'UTR (SNP) | VAF 53/125 reads (42%) | called by muse, mutect2, varscan2
- KLF7 | chr2:207167040 C>T | 5'Flank (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2
- KRT4 | c.*509T>G | 3'UTR (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- LGSN | c.163+1188C>T | Intron (SNP) | VAF 31/80 reads (39%) | catalogued as rs756547707, COSV65728712; called by muse, mutect2, varscan2
- LINC01101 | n.25C>T | RNA (SNP) | VAF 60/186 reads (32%) | catalogued as rs944440135; called by muse, mutect2, varscan2
- LRRIQ4 | c.*61G>A | 3'UTR (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- LY6K | c.*339G>A | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- M6PR | c.*18C>T | 3'UTR (SNP) | VAF 64/191 reads (34%) | called by muse, mutect2, varscan2
- MLLT3 | c.*960G>T | 3'UTR (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- MPO | c.*66C>A | 3'UTR (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- MRPS30 | c.*26G>A | 3'UTR (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- NEBL | c.*5432T>C | 3'UTR (SNP) | VAF 16/46 reads (35%) | catalogued as rs1232321830; called by muse, mutect2, varscan2
- NOP10 | c.-13C>T | 5'UTR (SNP) | VAF 58/236 reads (25%) | catalogued as rs772371219; called by muse, varscan2
- OR10D1P | n.45C>T | RNA (SNP) | VAF 56/192 reads (29%) | called by muse, mutect2, varscan2
- PCDH15 | c.*3634T>C | 3'UTR (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- PDP2 | c.*50T>G | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- PIPSL | n.2123C>T | RNA (SNP) | VAF 22/176 reads (13%) | catalogued as rs1564604530; called by muse, mutect2, varscan2
- PSMA6 | c.409+69T>C | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- RAB34 | c.-412C>A | 5'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- RBFOX1 | c.318+52T>A | Intron (SNP) | VAF 79/214 reads (37%) | called by muse, mutect2, varscan2
- RBM24 | c.*1343del | 3'UTR (DEL) | VAF 28/70 reads (40%) | catalogued as rs910817083; called by mutect2, varscan2
- RBM33 | c.*2785A>G | 3'UTR (SNP) | VAF 28/76 reads (37%) | catalogued as rs1277376228; called by muse, mutect2, varscan2
- RICTOR | c.*2195T>C | 3'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22603465 del G | 3'Flank (DEL) | VAF 59/315 reads (19%) | called by mutect2, pindel, varscan2
- ROPN1 | c.*12T>C | 3'UTR (SNP) | VAF 35/586 reads (6%) | called by muse, mutect2
- RRP15 | c.*1924A>G | 3'UTR (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*1366T>G | 3'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- SEMA3D | c.*2162G>T | 3'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- SLC36A1 | c.*161G>A | 3'UTR (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- SLC6A15 | c.756+1669A>G | Intron (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- SLC7A10 | c.912+18C>T | Intron (SNP) | VAF 34/231 reads (15%) | catalogued as rs993810768, COSV53503871; called by muse, mutect2, varscan2
- SMAD9 | c.*1586T>C | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- SPRED1 | c.*788T>A | 3'UTR (SNP) | VAF 28/90 reads (31%) | catalogued as COSV54437286; called by muse, varscan2
- SREK1IP1 | c.*2223A>C | 3'UTR (SNP) | VAF 35/125 reads (28%) | called by muse, mutect2, varscan2
- TEKT4 | c.-52G>A | 5'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as rs1394518690; called by muse, mutect2, varscan2
- TSLP | chr5:111071494 T>C | 5'Flank (SNP) | VAF 98/382 reads (26%) | called by muse, mutect2, varscan2
- TTC9C | c.-101C>T | 5'UTR (SNP) | VAF 130/510 reads (25%) | called by muse, mutect2, varscan2
- TXNIP | c.*1167A>G | 3'UTR (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- UBE2D3 | chr4:102797126 T>C | 3'Flank (SNP) | VAF 117/323 reads (36%) | catalogued as rs748404192; called by muse, mutect2, varscan2
- UBXN4 | c.-46C>T | 5'UTR (SNP) | VAF 38/106 reads (36%) | catalogued as rs1260825373; called by muse, mutect2, varscan2
- UNC5C | c.1733+58G>A | Intron (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- VPS39 | chr15:42159368 C>T | 3'Flank (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- WDR70 | c.*559A>G | 3'UTR (SNP) | VAF 30/108 reads (28%) | catalogued as rs1334715016; called by muse, mutect2, varscan2
- ZC3H12C | c.*1934A>G | 3'UTR (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- ZMYND8 | c.-46-1974T>C | Intron (SNP) | VAF 52/117 reads (44%) | called by muse, mutect2, varscan2
- ZNF211 | chr19:57642783 del T | 3'Flank (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- ZNF486 | c.-100G>C | 5'UTR (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- ZNF516 | chr18:76495535 A>T | 5'Flank (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
